Somatic mutation profile of tumor specimen TCGA-P7-A5NY-05A (aliquot TCGA-P7-A5NY-05A-11D-A35D-08) from TCGA case TCGA-P7-A5NY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 21.4 years (7,834 days).
Specimen TCGA-P7-A5NY-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee855324-1bb9-4607-9a0a-4f769b3c9da4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P7-A5NY-10A (Blood Derived Normal), aliquot TCGA-P7-A5NY-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad741a00-0b7e-40cb-b568-6fec73f00c97

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OCA2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769550106, COSV62353421, COSV62356115; called by muse, mutect2, varscan2
- COG1 | c.2737C>T p.L913F | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LTBP2 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- TNPO2 | c.140dup p.Y47* | Nonsense Mutation (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.2490C>T p.V830= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs778477000, COSV53670103; called by muse, mutect2, varscan2
